MMRF case MMRF_1522 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/c58cb4f8-b1bc-4dc6-b7ed-b847efbb66ab

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 42 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 42.8 years (15,624 days); ISS stage: II; Days to last known disease status: 1,325 days (3.6 years); Days to last follow up: 1,325 days (3.6 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 105 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 113 days; Days to treatment end: 113 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 114 days; Days to treatment end: 114 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 205 days; Days to treatment end: 1,291 days (3.5 years).
   Treatment given: Therapeutic agents: Ixazomib + Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,322 days (3.6 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6: M Protein 12.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 54.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.52 mg/dL; Immunoglobulin G 147 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 4.37 µg/mL; Lactate Dehydrogenase 3.97 µkat/L; Hemoglobin 5.02 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 2.54 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 126 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.6 mmol/L; Albumin 27 g/L; Total Protein 12 g/dL; Glucose 5.5 mmol/L; C-Reactive Protein 0.107 mg/dL.
- Day 67 (ECOG 0): M Protein 1.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.66 mg/dL; Immunoglobulin G 20.6 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.38 g/L; Beta 2 Microglobulin 1.45 µg/mL; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 8.5 ×10⁹/L; Absolute Neutrophil 4.76 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 49.5 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 34 g/L; Total Protein 7.5 g/dL; Glucose 6.66 mmol/L.
- Day 151 (ECOG 0): M Protein 0.78 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.12 mg/dL; Immunoglobulin G 16.4 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 1.81 µg/mL; Lactate Dehydrogenase 3.18 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 6.26 ×10⁹/L; Platelets 261 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 7.2 g/dL; Glucose 8.2 mmol/L.
- Day 261 (ECOG 0): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.994 mg/dL; Immunoglobulin G 15.7 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 1.8 µg/mL; Hemoglobin 6.7 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.35 mmol/L; Albumin 45 g/L; Total Protein 7.1 g/dL; Glucose 4.57 mmol/L.
- Day 359 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.21 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 0.78 g/L; Immunoglobulin M 0.47 g/L; Beta 2 Microglobulin 1.1 µg/mL; Hemoglobin 7.13 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.38 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 7.48 mmol/L.
- Day 408 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.5 mg/dL; Immunoglobulin G 13.6 g/L; Immunoglobulin A 1.04 g/L; Immunoglobulin M 0.37 g/L; Beta 2 Microglobulin 1.3 µg/mL; Hemoglobin 7.87 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 257 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.45 mmol/L; Albumin 46 g/L; Total Protein 7.3 g/dL; Glucose 5.89 mmol/L.
- Day 549 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.49 mg/dL; Immunoglobulin G 13.8 g/L; Immunoglobulin A 1.39 g/L; Immunoglobulin M 0.41 g/L; Beta 2 Microglobulin 1.2 µg/mL; Hemoglobin 7.69 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 284 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.45 mmol/L; Albumin 46 g/L; Total Protein 7.1 g/dL.
- Day 592: M Protein 0.26 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.04 mg/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 1 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 1 µg/mL; Lactate Dehydrogenase 4.65 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 4.3 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 6.6 g/dL; Glucose 6.11 mmol/L.
- Day 724 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.895 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.23 mg/dL; Immunoglobulin G 13.3 g/L; Immunoglobulin A 1.46 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 0.9 µg/mL; Hemoglobin 7.69 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 252 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.38 mmol/L; Albumin 37 g/L; Total Protein 6.8 g/dL; Glucose 4.51 mmol/L.
- Day 837: M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.74 mg/dL; Immunoglobulin G 13.9 g/L; Immunoglobulin A 1.87 g/L; Immunoglobulin M 0.4 g/L; Beta 2 Microglobulin 1.52 µg/mL; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 8.5 ×10⁹/L; Absolute Neutrophil 5.32 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 7.7 g/dL; Glucose 6.6 mmol/L.
- Day 912 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.41 mg/dL; Immunoglobulin G 13.9 g/L; Immunoglobulin A 1.61 g/L; Immunoglobulin M 0.37 g/L; Beta 2 Microglobulin 1.1 µg/mL; Hemoglobin 8 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 244 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.43 mmol/L; Albumin 44 g/L; Total Protein 7.3 g/dL; Glucose 4.29 mmol/L.
- Day 975 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.8 mg/dL; Immunoglobulin G 12.4 g/L; Immunoglobulin A 1.54 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 1 µg/mL; Hemoglobin 7.5 mmol/L; Leukocytes 3.7 ×10⁹/L; Platelets 223 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Glucose 5.01 mmol/L.
- Day 1,108 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.75 mg/dL; Immunoglobulin G 12.1 g/L; Immunoglobulin A 1.54 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 1 µg/mL; Hemoglobin 8 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 236 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.9 g/dL; Glucose 7.48 mmol/L.
- Day 1,201: M Protein 0.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.07 mg/dL; Immunoglobulin G 12.1 g/L; Immunoglobulin A 1.33 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 0.77 µg/mL; Lactate Dehydrogenase 3.55 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.44 ×10⁹/L; Platelets 150 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 6.71 mmol/L.
- Day 1,255 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.92 mg/dL; Immunoglobulin G 13.1 g/L; Immunoglobulin A 1.5 g/L; Immunoglobulin M 0.32 g/L; Beta 2 Microglobulin 1.1 µg/mL; Hemoglobin 7.69 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.24 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 7.04 mmol/L.
- Day 1,325 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.42 mg/dL; Immunoglobulin G 14.2 g/L; Immunoglobulin A 1.5 g/L; Immunoglobulin M 0.33 g/L; Beta 2 Microglobulin 1.1 µg/mL; Hemoglobin 7.63 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.77 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.33 mmol/L; Albumin 37 g/L; Total Protein 7 g/dL; Glucose 5.94 mmol/L.

Other clinical attributes
- Day -6: Weight: 63 kg; Height: 174 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Lymphoma.

Biospecimens (2 samples)
- Sample MMRF_1522_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_1522_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
